Gene-level copy-number profile of tumor specimen C3N-00175-02 from CPTAC case C3N-00175, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.5 years (26,470 days).
Specimen C3N-00175-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e225110-db7c-4c56-b12c-25978455bdc6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00175-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/87e33be6-e270-4525-a98a-074fc273cc7f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 536; copy number 1: 62; copy number 2: 13,481; copy number 3: 12,693; copy number 4: 18,699; copy number 5: 4,745; copy number 6: 5,395; copy number 7: 731; copy number 8: 1,935; copy number 9: 335; copy number 10: 203; copy number 11: 85.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,108,210–121,580,524, 12 genes: H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr9:63,581,254–63,859,641, 13 genes: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 623 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,258,885–147,517,875, 1 gene, copy number 9 (within-gene range 8–9): LINC00624.
- chr1:147,419,053–158,455,273, 536 genes, copy number 9–10 (broad region; genes not listed).
- chr1:160,392,768–161,964,070, 79 genes, copy number 11 (broad region; genes not listed).
- chr17:59,106,598–59,206,709, 7 genes, copy number 10–11 (within-gene range 6–11): AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P.

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
